Somatic mutation profile of tumor specimen TCGA-NC-A5HQ-01A (aliquot TCGA-NC-A5HQ-01A-11D-A26M-08) from TCGA case TCGA-NC-A5HQ, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.6 years (25,781 days).
Specimen TCGA-NC-A5HQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d8f8abf-29d6-48b4-af22-05b6f983b534.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NC-A5HQ-10A (Blood Derived Normal), aliquot TCGA-NC-A5HQ-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5ae79b7-16b2-4632-a9a9-28d937ac5a27

The open-access MAF lists 368 somatic variants for this specimen: 278 protein-altering or splice-affecting, 78 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 78, Nonsense Mutation 16, Frame Shift Del 8, Splice Site 7, Intron 4, RNA 4, In Frame Del 2, 3'UTR 2, 5'Flank 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 112/167 reads (67%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.577C>A p.H193N | Missense Mutation (SNP) | VAF 21/51 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.359G>T p.G120V | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100879499; called by muse, mutect2, varscan2
- ABCA13 | c.10160T>C p.L3387S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV101447203; called by muse, mutect2
- ABCC11 | c.4056+1G>T p.X1352_splice | Splice Site (SNP) | VAF 29/69 reads (42%) | catalogued as COSV100751130; called by muse, mutect2, varscan2
- AC090517.4 | c.1886C>T p.T629M | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.928); catalogued as rs751081566, COSV99975086; called by muse, mutect2
- ACSBG1 | c.816G>C p.Q272H | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.617); catalogued as COSV99357781; called by muse, mutect2, varscan2
- ACSBG2 | c.1037T>C p.F346S | Missense Mutation (SNP) | VAF 37/83 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as COSV99397641; called by muse, mutect2, varscan2
- ACTR3 | c.1244G>A p.G415E | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV54298511, COSV99603984; called by muse, mutect2, varscan2
- ADAMTS19 | c.1373-1G>A p.X458_splice | Splice Site (SNP) | VAF 23/163 reads (14%) | catalogued as COSV99180565; called by muse, mutect2, varscan2
- ADAMTS2 | c.2698A>T p.K900* | Nonsense Mutation (SNP) | VAF 41/104 reads (39%) | catalogued as COSV99283774; called by muse, mutect2, varscan2
- ADCY3 | c.1960G>T p.D654Y | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99569091; called by muse, mutect2, varscan2
- AGGF1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762216752, COSV57230349; called by muse, mutect2, varscan2
- AKAP12 | c.4328C>A p.T1443K | Missense Mutation (SNP) | VAF 33/128 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.366); catalogued as COSV53574459, COSV99484379; called by muse, mutect2, varscan2
- AL121899.2 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as COSV101198680, COSV67349775; called by muse, mutect2, varscan2
- ALKAL1 | c.215T>C p.L72S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100660279; called by muse, mutect2, varscan2
- AMY2A | c.587A>T p.E196V | Missense Mutation (SNP) | VAF 87/1130 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV101340673; called by muse, mutect2
- ANKRD36B | c.655A>T p.K219* | Nonsense Mutation (SNP) | VAF 52/168 reads (31%) | catalogued as COSV99308570; called by muse, mutect2, varscan2
- ANKS1B | c.2028A>T p.K676N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100247723; called by muse, mutect2, varscan2
- ARHGAP30 | c.1846C>A p.L616I | Missense Mutation (SNP) | VAF 42/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100920496; called by muse, mutect2, varscan2
- ARHGAP31 | c.4099A>T p.T1367S | Missense Mutation (SNP) | VAF 124/229 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.084); catalogued as COSV99957709; called by muse, mutect2, varscan2
- ARHGAP33 | c.2282del p.G761Afs*35 | Frame Shift Del (DEL) | VAF 10/75 reads (13%) | catalogued as rs774601323; called by pindel, varscan2*
- ARHGAP6 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 46/67 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as COSV57295311; called by muse, mutect2, varscan2
- ASCC3 | c.1889G>C p.R630P | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100226329; called by muse, mutect2, varscan2
- ATP10A | c.1875C>G p.I625M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.703); catalogued as COSV100791516; called by muse, mutect2, varscan2
- BNC2 | c.1398G>T p.K466N | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101034348; called by muse, mutect2, varscan2
- BRINP3 | c.1492A>T p.K498* | Nonsense Mutation (SNP) | VAF 44/188 reads (23%) | catalogued as COSV100819425; called by muse, mutect2, varscan2
- BRMS1 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.665); catalogued as COSV100240378; called by muse, varscan2
- BTBD7 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100598170, COSV58288219; called by muse, mutect2, varscan2
- BTBD9 | c.770G>C p.R257P | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100022714; called by muse, mutect2, varscan2
- BTN1A1 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.969); catalogued as COSV99764547; called by muse, mutect2, varscan2
- CA13 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs746847065, COSV100410344; called by muse, mutect2, varscan2
- CASP4 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as COSV101274220; called by muse, mutect2, varscan2
- CCDC62 | c.1469T>C p.M490T | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV99457682; called by muse, mutect2, varscan2
- CD1D | c.652G>T p.G218C | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100939659; called by muse, mutect2
- CD1E | c.19C>A p.L7I | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as COSV63772592; called by muse, mutect2, varscan2
- CDHR5 | c.1570C>A p.H524N (on ENST00000358353 / NM_001171968.2; = p.H530N on NM_021924.5) | Missense Mutation (SNP) | VAF 38/197 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.138); catalogued as COSV100363818; called by muse, mutect2, varscan2
- CELSR2 | c.8260G>T p.A2754S | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.031); catalogued as COSV54779944, COSV99604688; called by muse, mutect2, varscan2
- CFAP61 | c.2315G>T p.G772V | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99846593; called by muse, mutect2, varscan2
- CFAP61 | c.2615C>A p.S872Y | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.251); catalogued as COSV55628782, COSV99846597; called by muse, mutect2, varscan2
- CFAP92 | c.373C>A p.P125T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99414926; called by muse, mutect2, varscan2
- CHD5 | c.2583G>T p.R861S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.264); catalogued as COSV99314956; called by muse, mutect2, varscan2
- CKMT2 | c.570C>G p.N190K | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54174590, COSV99562489; called by muse, mutect2, varscan2
- CMYA5 | c.10123G>T p.V3375L | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.052); catalogued as COSV101484355; called by muse, mutect2, varscan2
- CNN1 | c.740T>G p.M247R | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99370733; called by muse, mutect2, varscan2
- COL1A2 | c.2375C>T p.A792V | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.172); catalogued as COSV99801033; called by muse, mutect2, varscan2
- COL26A1 | c.526T>A p.W176R (on ENST00000313669 / NM_001278563.3; = p.W174R on NM_133457.4) | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100562037; called by muse, mutect2, varscan2
- COL26A1 | c.655A>G p.K219E (on ENST00000313669 / NM_001278563.3; = p.K217E on NM_133457.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs745920589, COSV100562038; called by muse, varscan2
- COL2A1 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.022); catalogued as COSV100477430; called by muse, mutect2, varscan2
- COL6A2 | c.2938G>T p.V980L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV99385434; called by muse, mutect2
- COL6A6 | c.6430C>T p.L2144F | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100650908; called by muse, mutect2, varscan2
- COP1 | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100443888; called by muse, mutect2, varscan2
- CPNE4 | c.619T>A p.W207R | Missense Mutation (SNP) | VAF 133/261 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV70192768; called by muse, mutect2, varscan2
- CRISPLD2 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as COSV99296023; called by muse, mutect2, varscan2
- CRYBB2 | c.400G>T p.A134S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV101236772; called by muse, mutect2, varscan2
- CSMD1 | c.7486T>C p.C2496R (on ENST00000520002; = p.C2495R on NM_033225.6) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100153441; called by muse, mutect2, varscan2
- CSMD3 | c.8752A>T p.N2918Y (on ENST00000297405 / NM_001363185.1; = p.N2749Y on NM_052900.3) | Missense Mutation (SNP) | VAF 65/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99846965; called by muse, mutect2, varscan2
- CSMD3 | c.3065A>G p.Y1022C (on ENST00000297405 / NM_001363185.1; = p.Y918C on NM_052900.3) | Missense Mutation (SNP) | VAF 36/256 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as rs538363975, COSV99820692; called by muse, mutect2, varscan2
- CYP27C1 | c.419A>C p.D140A | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1284541743, COSV100080029; called by muse, mutect2
- DAAM2 | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.72); catalogued as rs373552829, COSV51422360; called by muse, mutect2, varscan2
- DACH1 | c.2140G>T p.A714S (on ENST00000619232 / NM_001366712.1; = p.A460S on NM_004392.6) | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.083); catalogued as rs757882645, COSV100499164; called by muse, mutect2, varscan2
- DCX | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 65/113 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.024); catalogued as COSV100576744; called by muse, mutect2, varscan2
- DDI1 | c.1111A>G p.R371G | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.357); catalogued as COSV100160789; called by muse, mutect2, varscan2
- DDX6 | c.264G>T p.S88= | Splice Region (SNP) | VAF 6/25 reads (24%) | catalogued as rs781874399, COSV99870662; called by muse, mutect2, varscan2
- DIDO1 | c.870A>C p.E290D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99827071; called by muse, mutect2, varscan2
- DOCK10 | c.5080A>T p.S1694C | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99291538; called by muse, mutect2, varscan2
- ECRG4 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV99430527; called by muse, mutect2, varscan2
- EEF1E1 | c.424G>A p.V142M | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV101121271; called by muse, mutect2, varscan2
- EGLN1 | c.1277T>C p.F426S | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); catalogued as COSV100791328; called by muse, mutect2, varscan2
- EHMT1 | c.2433G>A p.M811I | Missense Mutation (SNP) | VAF 69/143 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as COSV100604225; called by muse, mutect2, varscan2
- EIF4E1B | c.652A>G p.T218A | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.021); catalogued as COSV100024894; called by muse, varscan2
- ENPP1 | c.365G>T p.C122F | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719642; called by muse, mutect2, varscan2
- ERBB4 | c.3044A>T p.D1015V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.518); catalogued as rs769751950, COSV100727428; called by muse, mutect2, varscan2
- ESRRG | c.639G>T p.R213S | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); catalogued as COSV63182008; called by muse, mutect2, varscan2
- EVC2 | c.1413G>C p.Q471H | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60390416; called by muse, mutect2, varscan2
- F8 | c.1940C>T p.S647L | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV100811914, COSV64277169; called by muse, mutect2, varscan2
- FAM122A | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 59/113 reads (52%) | catalogued as COSV99599733; called by muse, mutect2, varscan2
- FAM135B | c.3824G>C p.G1275A | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99427361; called by muse, mutect2
- FAM135B | c.1810G>A p.A604T | Missense Mutation (SNP) | VAF 28/231 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs751330304, COSV52747497; called by muse, mutect2, varscan2
- FAM135B | c.1256C>G p.T419R | Missense Mutation (SNP) | VAF 28/219 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1404256029, COSV52721200, COSV99427367; called by muse, mutect2, varscan2
- FAM135B | c.887C>A p.P296Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV99427370; called by muse, mutect2
- FAM135B | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99358116; called by muse, mutect2, varscan2
- FER | c.1840C>T p.Q614* | Nonsense Mutation (SNP) | VAF 8/77 reads (10%) | catalogued as COSV99813913; called by muse, mutect2, varscan2
- FGF9 | c.184A>T p.R62W | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101211020; called by muse, mutect2, varscan2
- FGR | c.941G>A p.R314Q | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.558); catalogued as COSV100925918, COSV64969570; called by muse, mutect2, varscan2
- FH | c.1436G>A p.G479E | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100845072; called by muse, mutect2, varscan2
- FIG4 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100020234, COSV57790668; called by muse, mutect2, varscan2
- FPR2 | c.986C>A p.S329* | Nonsense Mutation (SNP) | VAF 14/104 reads (13%) | catalogued as COSV100389443; called by muse, mutect2, varscan2
- GALK2 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as rs201091452, COSV100508651, COSV100509136; called by muse, mutect2, varscan2
- GALNT12 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100899191; called by muse, mutect2, varscan2
- GLIS3 | c.1745C>A p.P582H | Missense Mutation (SNP) | VAF 60/89 reads (67%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.87); catalogued as rs1159397203, COSV100174587; called by muse, mutect2, varscan2
- GM2A | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.84); PolyPhen benign (0.015); catalogued as rs532003642, COSV100852050; called by muse, mutect2, varscan2
- GPAA1 | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100284209; called by muse, mutect2, varscan2
- GPATCH2 | c.1367G>T p.G456V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as COSV100861842; called by muse, mutect2, varscan2
- GRP | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as COSV99901083; called by muse, mutect2, varscan2
- GTF2A1 | c.612+1G>T p.X204_splice | Splice Site (SNP) | VAF 76/154 reads (49%) | catalogued as COSV99993558; called by muse, mutect2, varscan2
- GTF3C2 | c.1621C>G p.L541V | Missense Mutation (SNP) | VAF 104/260 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV99273254; called by muse, mutect2, varscan2
- H1-3 | c.43G>T p.A15S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as COSV99768888; called by muse, mutect2, varscan2
- HECW1 | c.44G>A p.R15K | Missense Mutation (SNP) | VAF 29/180 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV101224271; called by muse, mutect2, varscan2
- HELZ2 | c.1035G>T p.R345S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99069521; called by mutect2, varscan2
- HK1 | c.2735G>T p.R912L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100067924; called by muse, mutect2, varscan2
- HMGB3 | c.268C>A p.P90T | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV100308607; called by muse, mutect2, varscan2
- HMGCLL1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.393); catalogued as COSV99233165; called by muse, mutect2
- HSF4 | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as COSV50456837, COSV99263630; called by muse, mutect2, varscan2
- HTR2A | c.1012C>A p.P338T | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101096854; called by muse, mutect2, varscan2
- HUNK | c.1802C>A p.P601Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV54225612, COSV99528937; called by muse, mutect2, varscan2
- IFIT1B | c.1313A>G p.E438G | Missense Mutation (SNP) | VAF 149/375 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100879115; called by muse, mutect2, varscan2
- INF2 | c.2335G>T p.G779C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99384346; called by muse, mutect2
- INSYN2A | c.1418G>T p.R473I | Missense Mutation (SNP) | VAF 46/245 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732487; called by muse, mutect2, varscan2
- ISLR2 | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.069); catalogued as COSV100679774, COSV62302114; called by muse, mutect2, varscan2
- ITGAM | c.1417G>C p.D473H | Missense Mutation (SNP) | VAF 36/190 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54936900, COSV99793115; called by muse, mutect2, varscan2
- ITGB4 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99564720; called by muse, mutect2, varscan2
- ITPKB | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV99685146; called by muse, mutect2, varscan2
- JHY | c.2054A>T p.K685M | Missense Mutation (SNP) | VAF 68/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99913019; called by muse, mutect2, varscan2
- KCNA10 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 38/146 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871492; called by muse, mutect2, varscan2
- KCNK18 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 29/162 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs553050625, COSV100572140, COSV57972067; called by muse, mutect2, varscan2
- KCTD7 | c.599G>T p.S200I (on ENST00000275532; = p.E213D on NM_153033.5) | Missense Mutation (SNP) | VAF 50/160 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99299296; called by muse, mutect2, varscan2
- KIAA1549L | c.1623C>G p.N541K (on ENST00000321505; = p.N838K on NM_012194.3) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99684370; called by muse, mutect2, varscan2
- KIF18A | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99589094; called by muse, mutect2, varscan2
- KLHL4 | c.519G>T p.E173D | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV100910140; called by muse, mutect2, varscan2
- KMT2D | c.9224C>T p.S3075L | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV56410855; called by muse, mutect2, varscan2
- KMT2D | c.2128_2129insA p.P710Hfs*21 | Frame Shift Ins (INS) | VAF 48/147 reads (33%) | catalogued as COSV99985603; called by mutect2, pindel, varscan2
- KRTAP10-7 | c.536T>A p.V179E | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.904); catalogued as COSV100170312; called by muse, mutect2, varscan2
- LAMC1 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 70/246 reads (28%) | catalogued as COSV51133887, COSV99280399; called by muse, mutect2, varscan2
- LCMT2 | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751409095, COSV99980230; called by muse, mutect2, varscan2
- LCP2 | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 5/24 reads (21%) | catalogued as COSV99253504; called by muse, mutect2, varscan2
- LILRA2 | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV99253912; called by muse, mutect2, varscan2
- LPA | c.6085T>G p.F2029V | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV100308006; called by muse, mutect2, varscan2
- LRP1B | c.5518C>G p.L1840V | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101260643; called by muse, mutect2, varscan2
- LRP6 | c.241A>G p.N81D | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.146); catalogued as rs1240855104, COSV99744429; called by muse, mutect2, varscan2
- LRRIQ4 | c.1262C>G p.P421R | Missense Mutation (SNP) | VAF 76/98 reads (78%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.854); catalogued as COSV100540381; called by muse, mutect2, varscan2
- LURAP1 | c.685T>A p.W229R | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100915143; called by muse, mutect2, varscan2
- MAB21L1 | c.825G>T p.K275N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100084002, COSV59790725; called by muse, mutect2, varscan2
- MAG | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.09); catalogued as COSV100728047; called by muse, mutect2, varscan2
- MAGEA11 | c.218A>G p.E73G | Missense Mutation (SNP) | VAF 69/115 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.727); catalogued as COSV100290691; called by muse, mutect2, varscan2
- MAGEC3 | c.258G>T p.K86N | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV100026096, COSV53577218; called by muse, mutect2, varscan2
- MBTPS1 | c.699G>C p.E233D | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.075); catalogued as COSV100597789; called by muse, mutect2, varscan2
- MCM3AP | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99387485; called by muse, mutect2, varscan2
- MNT | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 40/70 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99437994; called by muse, mutect2, varscan2
- MOB2 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100326680; called by muse, mutect2, varscan2
- MOXD1 | c.1477A>T p.I493F | Missense Mutation (SNP) | VAF 32/203 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.194); catalogued as rs762337716, COSV100381926; called by muse, mutect2, varscan2
- MROH2B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV101270910; called by muse, mutect2, varscan2
- MTCL1 | c.2023C>T p.R675W (on ENST00000306329 / NM_001378206.1; = p.R315W on NM_015210.4) | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as rs780158820, COSV100095530; called by muse, mutect2, varscan2
- MUC16 | c.7910G>C p.G2637A | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.403); catalogued as COSV101201532; called by muse, mutect2, varscan2
- MUC5B | c.5320A>G p.N1774D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV101500742; called by muse, mutect2, varscan2
- MUC5B | c.12531G>T p.Q4177H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs1438854880; called by mutect2, varscan2
- MYBPC1 | c.1559-1G>T p.X520_splice (on ENST00000550270 / NM_206820.2; = p.X545_splice on NM_002465.4) | Splice Site (SNP) | VAF 14/83 reads (17%) | catalogued as COSV100638265; called by muse, mutect2, varscan2
- MYLK | c.2791C>T p.R931W | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs762375833, COSV60624498; called by muse, mutect2, varscan2
- NBN | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV99620071; called by muse, mutect2, varscan2
- NCKAP1 | c.1073C>G p.S358C | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.708); catalogued as COSV100720546; called by muse, mutect2, varscan2
- NCOA1 | c.1393A>T p.S465C | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99947032; called by muse, mutect2, varscan2
- NDUFV1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 57/267 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV100295414; called by muse, mutect2, varscan2
- NEXN | c.829G>C p.E277Q | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV99630548; called by muse, mutect2, varscan2
- NFRKB | c.2795C>G p.P932R (on ENST00000446488 / NM_001143835.2; = p.P957R on NM_006165.3) | Missense Mutation (SNP) | VAF 76/213 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV100452084; called by muse, mutect2, varscan2
- NIPBL | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 47/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM121322, COSV99242559; called by muse, mutect2, varscan2
- NKAIN2 | c.168A>T p.Q56H | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV100864109; called by muse, mutect2, varscan2
- NKX2-1 | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.305); catalogued as rs1459899247, COSV100702033; called by muse, mutect2, varscan2
- NKX3-1 | c.229A>T p.S77C | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.43); catalogued as COSV101082865; called by muse, mutect2, varscan2
- NLRP5 | c.2423C>A p.P808H | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV66763257; called by muse, mutect2, varscan2
- NMD3 | c.204G>C p.W68C | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100664808; called by muse, mutect2
- NOP2 | c.1709A>G p.Y570C (on ENST00000322166 / NM_001258308.2; = p.Y566C on NM_006170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs751715863, COSV100351353; called by muse, mutect2, varscan2
- NPC1 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 81/313 reads (26%) | catalogued as COSV99341921; called by muse, mutect2, varscan2
- NPHP1 | c.1249G>T p.V417F (on ENST00000393272 / NM_207181.4; = p.V418F on NM_000272.5) | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100338502; called by muse, mutect2, varscan2
- NRG3 | c.2033G>C p.S678T (on ENST00000404547 / NM_001370084.1; = p.S654T on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.318); catalogued as COSV100932338; called by muse, mutect2, varscan2
- OR13G1 | c.873T>G p.N291K | Missense Mutation (SNP) | VAF 48/171 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100687552; called by muse, mutect2, varscan2
- OR2L2 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 44/221 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs142994715, COSV63549338; called by muse, mutect2, varscan2
- OR4C15 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 33/154 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs752006238, COSV100116091; called by muse, mutect2, varscan2
- OR4D5 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100190177; called by muse, mutect2, varscan2
- OR5D16 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as COSV101004143, COSV65721854; called by muse, mutect2, varscan2
- PAK5 | c.1810G>T p.V604F | Missense Mutation (SNP) | VAF 65/161 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62027148, COSV62031211; called by muse, mutect2, varscan2
- PCDHB12 | c.1495C>T p.P499S | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.1); catalogued as COSV53398121; called by muse, mutect2, varscan2
- PCDHB14 | c.1123T>A p.S375T | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV99506263; called by muse, mutect2, varscan2
- PCSK7 | c.94G>T p.V32F | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.055); catalogued as COSV100309525; called by muse, mutect2, varscan2
- PDE10A | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100605726; called by muse, mutect2, varscan2
- PDE10A | c.503C>A p.S168Y | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV100605729; called by muse, mutect2, varscan2
- PDE9A | c.959T>C p.V320A | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372190; called by muse, mutect2, varscan2
- PDZRN3 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV99731982; called by muse, mutect2, varscan2
- PER3 | c.1665G>C p.L555F | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100728477; called by muse, mutect2
- PIK3R1 | c.1891C>T p.R631* (on ENST00000521381 / NM_181523.3; = p.R361* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 32/163 reads (20%) | catalogued as rs761888083, COSV57134805; called by muse, mutect2, varscan2
- PIKFYVE | c.2298A>T p.E766D | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as COSV100011411; called by muse, mutect2, varscan2
- PIP4K2A | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV100114661, COSV60542894; called by muse, mutect2, varscan2
- PLXNA4 | c.2751G>C p.E917D | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.911); catalogued as COSV100326881; called by muse, mutect2, varscan2
- PODN | c.1220A>T p.K407M (on ENST00000395871; = p.K359M on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV100439832; called by muse, mutect2, varscan2
- POGLUT2 | c.388+2T>A p.X130_splice | Splice Site (SNP) | VAF 8/44 reads (18%) | catalogued as COSV99959084; called by mutect2, varscan2
- POLE | c.4728+1G>T p.X1576_splice | Splice Site (SNP) | VAF 61/176 reads (35%) | catalogued as COSV100268137; called by muse, mutect2, varscan2
- POM121L12 | c.48G>T p.W16C | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV101374979; called by muse, mutect2
- POMGNT2 | c.208A>T p.T70S | Missense Mutation (SNP) | VAF 35/49 reads (71%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV100768143; called by muse, mutect2, varscan2
- PPFIA2 | c.2470G>T p.A824S | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.124); catalogued as COSV100335165; called by muse, mutect2, varscan2
- PPIL6 | c.484-1G>C p.X162_splice | Splice Site (SNP) | VAF 20/105 reads (19%) | catalogued as rs1157396351, COSV101329715; called by muse, mutect2, varscan2
- PRB2 | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 55/450 reads (12%) | SIFT tolerated (1); PolyPhen possibly damaging (0.839); catalogued as COSV101231494, COSV101231496, COSV66983207; called by muse, mutect2, varscan2
- PRKCG | c.1910G>A p.G637D | Missense Mutation (SNP) | VAF 44/575 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV99669519; called by muse, mutect2
- PRR16 | c.370C>G p.P124A (on ENST00000407149 / NM_001300783.2; = p.P101A on NM_016644.2) | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1196027585, COSV101087959; called by muse, mutect2, varscan2
- PSMD14 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.22); catalogued as COSV101293957; called by muse, mutect2, varscan2
- PSMG3 | c.211G>T p.D71Y | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99365888, COSV99365897; called by muse, mutect2
- PTGER2 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV99817745; called by muse, mutect2, varscan2
- PTPRM | c.2166A>T p.K722N | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100160248; called by muse, mutect2, varscan2
- PYHIN1 | c.793A>T p.K265* | Nonsense Mutation (SNP) | VAF 13/107 reads (12%) | catalogued as COSV100932413; called by muse, mutect2, varscan2
- RALYL | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.449); catalogued as rs1433236969, COSV101569435; called by muse, mutect2, varscan2
- RAPGEF6 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV99727828; called by muse, mutect2, varscan2
- RBAK | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750161506, COSV100806765; called by muse, mutect2, varscan2
- RGS18 | c.119G>C p.R40T | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.725); catalogued as COSV100817899; called by muse, mutect2, varscan2
- RHOBTB1 | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100558557, COSV100558675; called by muse, mutect2, varscan2
- RNF19B | c.1702G>T p.A568S | Missense Mutation (SNP) | VAF 40/161 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.265); catalogued as COSV99331720; called by muse, mutect2, varscan2
- ROBO4 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.898); catalogued as COSV100127861; called by muse, mutect2, varscan2
- RSRP1 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.217); catalogued as COSV99682726; called by muse, mutect2, varscan2
- RYR2 | c.11938G>C p.V3980L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100772783; called by muse, mutect2, varscan2
- RYR3 | c.10289T>C p.L3430P (on ENST00000389232; = p.L3431P on NM_001036.6) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101214426; called by muse, mutect2, varscan2
- S1PR1 | c.689C>A p.T230N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs757624744, COSV100541673; called by muse, mutect2, varscan2
- SCGN | c.169G>A p.A57T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs148531052; called by muse, mutect2, varscan2
- SCN5A | c.3279G>T p.R1093S (on ENST00000333535 / NM_198056.3; = p.R1092S on NM_000335.5) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.025); catalogued as rs1225014803, COSV100350475; called by muse, mutect2, varscan2
- SCUBE2 | c.2096C>T p.T699I (on ENST00000649792 / NM_001367977.2; = p.T544I on NM_001170690.2) | Missense Mutation (SNP) | VAF 55/214 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1184469110, COSV100496929; called by muse, mutect2, varscan2
- SCUBE2 | c.1284G>T p.Q428H | Missense Mutation (SNP) | VAF 67/228 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV100496930; called by muse, mutect2, varscan2
- SEMA3E | c.1814G>C p.R605P | Missense Mutation (SNP) | VAF 56/223 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100319578, COSV57108396; called by muse, mutect2, varscan2
- SEMA3E | c.714C>A p.D238E | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV100319579; called by muse, mutect2, varscan2
- SGSM1 | c.3164G>T p.R1055L (on ENST00000400359 / NM_001039948.4; = p.R994L on NM_133454.3) | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1388940370, COSV101241146, COSV68509593; called by muse, mutect2, varscan2
- SH2D5 | c.1090A>C p.S364R (on ENST00000444387 / NM_001103161.2; = p.S280R on NM_001103160.2) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99929720; called by muse, mutect2, varscan2
- SIGLEC14 | c.637T>C p.C213R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99707895; called by muse, mutect2, varscan2
- SLC24A3 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100042978; called by muse, mutect2, varscan2
- SLC4A3 | c.1678G>T p.G560W | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99813199; called by muse, mutect2, varscan2
- SLCO1C1 | c.1462G>T p.E488* | Nonsense Mutation (SNP) | VAF 102/185 reads (55%) | catalogued as COSV56870975, COSV99858720; called by muse, mutect2, varscan2
- SLITRK2 | c.822G>C p.R274S | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.069); catalogued as COSV100158197, COSV59423320, COSV59427135; called by muse, mutect2, varscan2
- SMCHD1 | c.3214C>A p.Q1072K | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.543); catalogued as COSV55251631, COSV99861763; called by muse, mutect2, varscan2
- SNTG2 | c.661T>C p.S221P | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100424698; called by muse, mutect2, varscan2
- SOX3 | c.560C>A p.P187Q | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100983757; called by muse, mutect2, varscan2
- SPHKAP | c.3952A>T p.M1318L | Missense Mutation (SNP) | VAF 54/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100764526; called by muse, mutect2, varscan2
- SPINK1 | c.203A>G p.Q68R | Missense Mutation (SNP) | VAF 21/113 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.462); catalogued as rs760077990, CM066605, COSV57024951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPOCD1 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99930346; called by muse, mutect2, varscan2
- SRRM3 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.509); catalogued as rs781833246, COSV100418881; called by muse, mutect2, varscan2
- STPG2 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99761497; called by muse, mutect2, varscan2
- STT3A | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.042); catalogued as COSV101205281; called by muse, mutect2, varscan2
- SV2B | c.1214A>G p.Y405C | Missense Mutation (SNP) | VAF 49/198 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1226024035, COSV100370994; called by muse, mutect2, varscan2
- TAS2R30 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 183/340 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.277); catalogued as COSV67858829; called by muse, mutect2, varscan2
- TAS2R30 | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV101115573; called by muse, varscan2
- TBR1 | c.864G>A p.M288I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.061); catalogued as rs755926306, COSV101271538; called by muse, mutect2, varscan2
- TCF12 | c.1144C>A p.Q382K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as CM156036, COSV51015225, COSV99978892; called by muse, mutect2, varscan2
- TCL1B | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100525853; called by muse, mutect2, varscan2
- TEKT5 | c.1201C>A p.R401S | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99296389; called by muse, mutect2, varscan2
- TET1 | c.6194A>T p.K2065M | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV101018859; called by muse, mutect2, varscan2
- THSD7A | c.2402G>T p.R801L | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101448887; called by muse, mutect2, varscan2
- TIFAB | c.47C>G p.T16R | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.204); catalogued as COSV101538278, COSV72345933; called by muse, mutect2, varscan2
- TJP2 | c.3294G>T p.Q1098H | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.864); catalogued as COSV99601816; called by muse, mutect2, varscan2
- TMEM132E | c.2212A>T p.S738C (on ENST00000321639; = p.S828C on NM_001304438.2) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.753); catalogued as COSV100396766; called by muse, mutect2, varscan2
- TTN | c.46439T>A p.V15480D (on ENST00000591111; = p.V8056D on NM_003319.4) | Missense Mutation (SNP) | VAF 40/187 reads (21%) | PolyPhen probably damaging (0.998); catalogued as COSV100629016; called by muse, mutect2, varscan2
- TTN | c.39814G>T p.D13272Y (on ENST00000591111; = p.D5848Y on NM_003319.4) | Missense Mutation (SNP) | VAF 25/131 reads (19%) | PolyPhen benign (0.413); catalogued as COSV100629019; called by muse, mutect2, varscan2
- USP7 | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV61215607; called by muse, mutect2, varscan2
- VWA8 | c.4999G>A p.E1667K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101022955; called by muse, mutect2, varscan2
- WBP2NL | c.562G>T p.G188* | Nonsense Mutation (SNP) | VAF 41/225 reads (18%) | catalogued as COSV100173925; called by muse, mutect2, varscan2
- WDR17 | c.3404C>A p.P1135H | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV99708247; called by muse, mutect2, varscan2
- WIPF2 | c.1102G>T p.A368S | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100063913; called by muse, mutect2, varscan2
- XIRP2 | c.230C>A p.P77H (on ENST00000628543; = p.P252H on NM_152381.6) | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99747146; called by muse, mutect2, varscan2
- XIRP2 | c.4130T>C p.I1377T (on ENST00000628543; = p.I1552T on NM_152381.6) | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99747150; called by muse, mutect2, varscan2
- ZDBF2 | c.4173G>T p.W1391C | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100985514; called by muse, mutect2, varscan2
- ZIK1 | c.1107C>A p.H369Q | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100277353, COSV100277654; called by muse, mutect2, varscan2
- ZMAT1 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 73/115 reads (63%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV100858929; called by muse, mutect2, varscan2
- ZNF2 | c.1067G>T p.C356F (on ENST00000611147 / NM_001291605.2; = p.C343F on NM_021088.4) | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99728679; called by muse, mutect2, varscan2
- ZNF263 | c.1102C>T p.R368* | Nonsense Mutation (SNP) | VAF 25/103 reads (24%) | catalogued as rs755524071, COSV54596580; called by muse, mutect2, varscan2
- ZNF284 | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101399093, COSV69691258; called by muse, mutect2, varscan2
- ZNF385D | c.976del p.E326Nfs*15 | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as COSV55755827; called by mutect2, pindel, varscan2
- ZNF479 | c.1216G>A p.E406K | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.586); catalogued as COSV100483050; called by muse, mutect2, varscan2
- ZNF521 | c.2083A>G p.I695V | Missense Mutation (SNP) | VAF 82/228 reads (36%) | SIFT tolerated (0.99); PolyPhen benign (0.08); catalogued as COSV100833348; called by muse, mutect2, varscan2
- ZNF543 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100386925; called by muse, mutect2, varscan2
- ZNF585B | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 51/280 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV100459636; called by muse, mutect2, varscan2
- ZNF610 | c.271A>G p.I91V | Missense Mutation (SNP) | VAF 45/140 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100017006; called by muse, mutect2, varscan2
- ZNF695 | c.1438T>A p.S480T | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100377729; called by muse, mutect2, varscan2
- ZNF704 | c.1048C>T p.H350Y | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV100589854; called by muse, mutect2, varscan2
- ZNF804B | c.2485G>A p.D829N | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.03); catalogued as rs769658903, COSV60818783, COSV60833695; called by muse, mutect2, varscan2
- AKNA | c.1102del p.V368* | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- C17orf75 | c.1156_1158del p.E386del | In Frame Del (DEL) | VAF 10/79 reads (13%) | called by pindel, varscan2
- DCAF1 | c.1872G>T p.L624F | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- EBF1 | c.1437del p.N480Tfs*9 | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | called by mutect2, pindel, varscan2
- GFOD1 | c.9del p.V5Wfs*17 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- GJB4 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.147); called by muse, mutect2
- IGKV3-7 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 64/204 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- LYZL6 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- OR4K1 | c.922_923del p.S308Lfs*17 | Frame Shift Del (DEL) | VAF 42/193 reads (22%) | called by mutect2, pindel, varscan2
- OR51B4 | c.409del p.R137Efs*2 | Frame Shift Del (DEL) | VAF 19/114 reads (17%) | called by mutect2, pindel, varscan2
- SASS6 | c.1718_1720del p.G573del | In Frame Del (DEL) | VAF 17/106 reads (16%) | called by mutect2, pindel, varscan2
- TRDV1 | c.55_65del p.S19Efs*24 | Frame Shift Del (DEL) | VAF 36/300 reads (12%) | called by mutect2, pindel
- ABCA9 | c.285T>A p.A95= | Silent (SNP) | VAF 50/126 reads (40%) | catalogued as COSV100383465; called by muse, mutect2, varscan2
- ABCD2 | c.789G>A p.V263= | Silent (SNP) | VAF 49/151 reads (32%) | catalogued as COSV100429779; called by muse, mutect2, varscan2
- ADAMTS7 | c.447C>T p.C149= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs1314992980, COSV101183250; called by muse, mutect2, varscan2
- ANKRD26 | c.4341A>G p.L1447= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as rs1255214919, COSV101063391; called by muse, mutect2, varscan2
- ARSD | c.411G>A p.Q137= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99472373; called by muse, mutect2, varscan2
- BCL9 | c.1476C>G p.V492= | Silent (SNP) | VAF 58/161 reads (36%) | catalogued as COSV52341418, COSV99325796; called by muse, mutect2, varscan2
- C9orf78 | c.111A>T p.V37= | Silent (SNP) | VAF 56/96 reads (58%) | catalogued as COSV100204745, COSV100204924; called by muse, mutect2, varscan2
- CACNB2 | c.510C>T p.I170= (on ENST00000324631 / NM_201596.3; = p.I115= on NM_000724.4) | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs760606646, COSV56636419; called by muse, mutect2, varscan2
- CADM1 | c.972G>T p.S324= | Silent (SNP) | VAF 57/225 reads (25%) | catalogued as rs745677210, COSV100523363, COSV59023029; called by muse, mutect2, varscan2
- CAMSAP1 | c.1608G>A p.E536= | Silent (SNP) | VAF 88/197 reads (45%) | catalogued as COSV100410428; called by muse, mutect2, varscan2
- CCDC88C | c.2991G>A p.E997= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV101106061; called by muse, mutect2, varscan2
- COL12A1 | c.582A>G p.L194= | Silent (SNP) | VAF 31/141 reads (22%) | catalogued as COSV100486466; called by muse, mutect2, varscan2
- CSF1R | c.2514C>A p.V838= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV99642995; called by muse, mutect2, varscan2
- CTCFL | c.1173G>T p.T391= | Silent (SNP) | VAF 33/231 reads (14%) | catalogued as rs376178878, COSV99713290; called by muse, mutect2, varscan2
- CTNS | c.864C>T p.N288= | Silent (SNP) | VAF 21/43 reads (49%) | catalogued as CM023360, COSV99251543; called by muse, mutect2, varscan2
- DAB1 | c.654C>T p.N218= | Silent (SNP) | VAF 8/165 reads (5%) | catalogued as rs1391058847, COSV100140772; called by muse, mutect2
- DCBLD2 | c.2184C>T p.A728= | Silent (SNP) | VAF 46/370 reads (12%) | catalogued as rs374392851; called by muse, mutect2, varscan2
- DIAPH3 | c.3558G>T p.L1186= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as rs752894201, COSV100931165; called by muse, mutect2, varscan2
- DMRTA2 | c.975A>T p.P325= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV101288908; called by muse, mutect2, varscan2
- DNM1L | c.9G>A p.A3= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99846434; called by muse, varscan2
- DNM1L | c.10C>T p.L4= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV56779383; called by muse, mutect2, varscan2
- DNPEP | c.186G>A p.E62= | Silent (SNP) | VAF 39/105 reads (37%) | catalogued as COSV99815402; called by muse, mutect2, varscan2
- DPPA2 | c.546G>T p.P182= | Silent (SNP) | VAF 34/256 reads (13%) | catalogued as COSV101524757; called by muse, mutect2, varscan2
- DSCAML1 | c.2112C>A p.T704= (on ENST00000321322; = p.T644= on NM_020693.4) | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV100357177, COSV58388922; called by muse, mutect2, varscan2
- DUSP14 | c.9C>T p.S3= | Silent (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- EHD3 | c.60G>A p.T20= | Silent (SNP) | VAF 46/146 reads (32%) | catalogued as rs374598778; called by muse, mutect2, varscan2
- ERCC3 | c.849T>C p.R283= | Silent (SNP) | VAF 96/241 reads (40%) | catalogued as COSV99573660; called by muse, mutect2, varscan2
- EXOC3L1 | c.528G>A p.T176= | Silent (SNP) | VAF 27/58 reads (47%) | catalogued as rs745345276, COSV99333951; called by muse, mutect2, varscan2
- FAM135B | c.1935T>C p.S645= | Silent (SNP) | VAF 23/152 reads (15%) | catalogued as COSV52718115, COSV99427364; called by muse, mutect2, varscan2
- FFAR2 | c.894G>T p.L298= | Silent (SNP) | VAF 25/127 reads (20%) | catalogued as COSV99876180; called by muse, mutect2, varscan2
- FOXD2 | c.537C>T p.L179= | Silent (SNP) | VAF 29/150 reads (19%) | catalogued as rs766279635, COSV100599312; called by muse, mutect2, varscan2
- FOXN4 | c.948C>T p.R316= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100142299; called by muse, mutect2, varscan2
- GNPDA1 | c.15C>A p.I5= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100257681; called by muse, mutect2, varscan2
- GPR26 | c.810C>A p.P270= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as COSV99501093; called by muse, mutect2, varscan2
- H2AC8 | c.363G>A p.T121= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs760636792, COSV99773384; called by muse, mutect2, varscan2
- HDAC1 | c.387G>C p.T129= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV101000519; called by muse, mutect2, varscan2
- IGHV4-31 | c.312C>T p.S104= | Silent (SNP) | VAF 74/552 reads (13%) | catalogued as rs542101511; called by muse, mutect2
- IGKV1-16 | c.168C>T p.A56= | Silent (SNP) | VAF 159/444 reads (36%) | catalogued as rs549148592; called by muse, mutect2, varscan2
- KIAA1109 | c.5952A>G p.K1984= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as COSV99175017; called by muse, mutect2, varscan2
- KRTAP10-8 | c.249C>A p.P83= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100555412; called by muse, mutect2, varscan2
- KRTAP5-7 | c.372C>T p.S124= | Silent (SNP) | VAF 57/485 reads (12%) | catalogued as rs879097279, COSV101273242; called by muse, varscan2
- LOX | c.927C>T p.A309= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV50238315; called by muse, mutect2, varscan2
- MAGEC1 | c.1317C>A p.P439= | Silent (SNP) | VAF 116/192 reads (60%) | catalogued as rs781630319, COSV99594791, COSV99596482; called by muse, varscan2
- MAGEC1 | c.3015T>C p.S1005= | Silent (SNP) | VAF 94/141 reads (67%) | catalogued as COSV99596483; called by muse, mutect2, varscan2
- MAST2 | c.3021A>T p.S1007= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100788744; called by muse, mutect2
- MED13 | c.6114C>T p.G2038= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV101181372; called by muse, mutect2, varscan2
- MUC3A | c.8568C>A p.P2856= | Silent (SNP) | VAF 86/343 reads (25%) | catalogued as COSV100115346; called by muse, mutect2, varscan2
- MUC5B | c.13143C>A p.T4381= | Silent (SNP) | VAF 32/153 reads (21%) | catalogued as rs560210224, COSV101500743; called by muse, mutect2, varscan2
- MYO3A | c.57T>C p.D19= | Silent (SNP) | VAF 72/210 reads (34%) | catalogued as COSV99781466; called by muse, varscan2
- NPTX1 | c.1053C>T p.G351= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs377227227, COSV100151186; called by muse, mutect2, varscan2
- NUMA1 | c.4068G>T p.L1356= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV100706587; called by muse, mutect2, varscan2
- OR2T2 | c.525C>A p.I175= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as COSV100737614, COSV61617886; called by mutect2, varscan2
- OR52N2 | c.123C>T p.V41= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs112125234, COSV100396225; called by muse, mutect2, varscan2
- PCDHA13 | c.1278C>A p.T426= | Silent (SNP) | VAF 79/254 reads (31%) | catalogued as COSV56522229, COSV99169696; called by muse, mutect2, varscan2
- PCDHGA10 | c.642G>T p.L214= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV99546456; called by muse, mutect2, varscan2
- PCSK7 | c.93G>T p.L31= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as COSV100309527; called by muse, mutect2, varscan2
- PDZRN3 | c.2406G>A p.G802= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV99731978; called by muse, mutect2, varscan2
- PDZRN3 | c.114C>T p.C38= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV55207060, COSV99731985; called by muse, mutect2
- PIWIL3 | c.2502T>C p.Y834= | Silent (SNP) | VAF 28/118 reads (24%) | catalogued as rs1022445001, COSV100177957; called by muse, mutect2, varscan2
- PKHD1L1 | c.5319G>C p.G1773= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV101006801, COSV65750948; called by muse, mutect2, varscan2
- PTPN11 | c.1242G>T p.T414= | Silent (SNP) | VAF 34/83 reads (41%) | catalogued as rs552394167, COSV100692858, COSV61010338; called by muse, mutect2, varscan2
- PWWP3A | c.366G>A p.G122= (on ENST00000627377; = p.G121= on NM_032853.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 29/105 reads (28%) | catalogued as COSV100262256; called by muse, mutect2, varscan2
- SAGE1 | c.762T>C p.P254= | Silent (SNP) | VAF 69/106 reads (65%) | catalogued as COSV100187882; called by muse, mutect2, varscan2
- SEC14L5 | c.1314C>T p.F438= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs868459277, COSV99229401; called by muse, mutect2
- SLC22A15 | c.1221G>A p.G407= | Silent (SNP) | VAF 79/269 reads (29%) | catalogued as COSV101048071; called by muse, mutect2, varscan2
- SLC25A24 | c.1433G>A p.*478= | Silent (SNP) | VAF 27/97 reads (28%) | catalogued as COSV99916632; called by muse, mutect2, varscan2
- SLC41A1 | c.435C>A p.L145= | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV100900496; called by muse, mutect2, varscan2
- SLC5A5 | c.669C>A p.A223= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as COSV55831996; called by muse, mutect2, varscan2
- SPNS1 | c.669A>C p.T223= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as COSV100209270; called by muse, mutect2, varscan2
- SPTB | c.5469C>T p.D1823= | Silent (SNP) | VAF 25/160 reads (16%) | catalogued as rs374916785; called by muse, mutect2, varscan2
- SYNE2 | c.17748C>A p.L5916= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as COSV100648458; called by muse, mutect2, varscan2
- TAS2R31 | c.405G>A p.G135= | Silent (SNP) | VAF 26/228 reads (11%) | catalogued as COSV101115568, COSV66829756; called by muse, mutect2, varscan2
- THSD7A | c.2403G>T p.R801= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as rs1367006764, COSV101448886; called by muse, mutect2, varscan2
- TRIM5 | c.357G>A p.R119= | Silent (SNP) | VAF 28/111 reads (25%) | catalogued as COSV100000716; called by muse, mutect2, varscan2
- UAP1 | c.333G>A p.G111= | Silent (SNP) | VAF 33/245 reads (13%) | catalogued as COSV99618063; called by muse, mutect2, varscan2
- VIP | c.18G>A p.K6= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV100923964; called by muse, mutect2, varscan2
- WIPF2 | c.912A>G p.P304= | Silent (SNP) | VAF 56/118 reads (47%) | catalogued as COSV100063909; called by muse, mutect2, varscan2
- YEATS2 | c.4227C>T p.F1409= | Silent (SNP) | VAF 91/109 reads (83%) | catalogued as rs758014812, COSV59371020; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288278C>A | Intron (SNP) | VAF 62/99 reads (63%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81147371 C>A | 5'Flank (SNP) | VAF 68/162 reads (42%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498571 G>A | 5'Flank (SNP) | VAF 8/60 reads (13%) | called by muse, mutect2, varscan2
- CSPP1 | c.535-1710C>T | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as COSV99139847; called by muse, mutect2
- HERC2P3 | n.2094G>T | RNA (SNP) | VAF 21/73 reads (29%) | called by mutect2, varscan2
- MIR527 | n.24A>G | RNA (SNP) | VAF 65/623 reads (10%) | called by muse, mutect2, varscan2
- PKD1L2 | n.4716C>T | RNA (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- RIMS2 | c.1692+199G>A | Intron (SNP) | VAF 47/221 reads (21%) | catalogued as COSV99198633; called by muse, mutect2, varscan2
- SEPTIN4 | c.1606+89T>A | Intron (SNP) | VAF 59/273 reads (22%) | catalogued as COSV100400444; called by muse, mutect2, varscan2
- TPH2 | c.*1T>A | 3'UTR (SNP) | VAF 133/264 reads (50%) | catalogued as COSV100421877; called by muse, mutect2, varscan2
- TUBB7P | n.150C>G | RNA (SNP) | VAF 9/33 reads (27%) | catalogued as rs1304898012; called by muse, mutect2, varscan2
- VCAN | c.*2C>A | 3'UTR (SNP) | VAF 26/82 reads (32%) | catalogued as COSV99427225; called by muse, mutect2, varscan2
